Somatic mutation profile of tumor specimen TCGA-DV-5573-01A (aliquot TCGA-DV-5573-01A-01D-1534-10) from TCGA case TCGA-DV-5573, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 41.8 years (15,264 days).
Specimen TCGA-DV-5573-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0576dce-de8a-4ab7-803c-ace814b7a889.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-5573-10A (Blood Derived Normal), aliquot TCGA-DV-5573-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1aff0390-4273-4f91-b521-e50b47fd41de

The open-access MAF lists 35 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 27, Silent 5, Nonsense Mutation 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.2277G>A p.S759= | Splice Region (SNP) | VAF 172/626 reads (27%) | catalogued as rs765558703, COSV52202939; called by muse, mutect2, varscan2
- ADGRL2 | c.2854T>A p.Y952N (on ENST00000370717 / NM_001366005.1; = p.Y939N on NM_012302.4) | Missense Mutation (SNP) | VAF 134/578 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1257035314; called by muse, mutect2, varscan2
- CORIN | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs571200712, COSV56689128; called by muse, mutect2, varscan2
- DTX3 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV54086065; called by muse, mutect2, varscan2
- GRIK1 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs765040687; called by muse, mutect2, varscan2
- LGALS2 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV50755586; called by muse, mutect2, varscan2
- MCTP2 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100537225; called by muse, mutect2
- PKD2L1 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 49/224 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs1404081116, COSV58396568; called by muse, mutect2, varscan2
- SLC6A5 | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 36/624 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs143967107; called by muse, mutect2
- XDH | c.3475G>A p.A1159T | Missense Mutation (SNP) | VAF 106/359 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs1346751155; called by muse, varscan2
- BNC2 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CD163 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- EPHX1 | c.576G>T p.E192D | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.075); called by muse, mutect2
- FAM135A | c.685A>G p.I229V (on ENST00000370479 / NM_001351599.1; = p.I186V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/406 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO44 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- H4C3 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2
- HELB | c.1048T>C p.C350R | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- HPS3 | c.1559A>G p.H520R | Missense Mutation (SNP) | VAF 72/300 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INSR | c.3625A>G p.K1209E | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- LYST | c.5642T>A p.L1881H | Missense Mutation (SNP) | VAF 93/328 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIGU | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PTPRF | c.4117G>A p.E1373K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- RAB27B | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 153/510 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAMD10 | c.380T>G p.L127R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- THAP6 | c.10T>C p.C4R | Missense Mutation (SNP) | VAF 134/498 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- TRIOBP | c.3341_3347del p.I1114Tfs*97 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- ZBTB1 | c.92A>C p.D31A | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ZEB2 | c.71A>C p.N24T | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF638 | c.698T>C p.I233T | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.395); called by muse, varscan2
- ZNF81 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BIN1 | c.1182C>T p.D394= | Silent (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- CBLL1 | c.1098C>T p.H366= | Silent (SNP) | VAF 49/190 reads (26%) | called by muse, mutect2, varscan2
- KDM3A | c.1567C>T p.L523= | Silent (SNP) | VAF 65/200 reads (33%) | catalogued as rs145137870; called by muse, mutect2, varscan2
- NLGN2 | c.1323G>A p.R441= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs1434687804; called by muse, mutect2, varscan2
- RALGPS1 | c.204T>C p.A68= | Silent (SNP) | VAF 173/676 reads (26%) | called by muse, mutect2, varscan2
